Somatic mutation profile of tumor specimen HTMCP-03-06-02121-01A (aliquot HTMCP-03-06-02121-01A-01D-5099) from CGCI case HTMCP-03-06-02121, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.6 years (19,959 days).
Specimen HTMCP-03-06-02121-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7baba631-89a6-47ff-8b47-1eeb465c06f1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02121-10A (Blood Derived Normal), aliquot HTMCP-03-06-02121-10A-01D-5099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bbe8c37-8e00-455b-baa5-0310c0916721

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 12, Nonsense Mutation 1, IGR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CASS4 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs73159591; called by muse, mutect2, varscan2
- CUX2 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs527685575, COSV55634028; called by muse, mutect2, varscan2
- FLG | c.10715G>A p.R3572K | Missense Mutation (SNP) | VAF 61/306 reads (20%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.983); catalogued as COSV64242148; called by muse, varscan2
- GOLGB1 | c.8566C>T p.R2856* | Nonsense Mutation (SNP) | VAF 17/140 reads (12%) | catalogued as COSV61466135, COSV61468228; called by muse, mutect2, varscan2
- IMPG2 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as COSV51986912; called by muse, mutect2, varscan2
- KDR | c.2974C>G p.P992A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV55757192, COSV55767520; called by muse, mutect2, varscan2
- LAMA1 | c.3892A>T p.N1298Y | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746999059; called by muse, mutect2, varscan2
- MAP3K7 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV65225916; called by muse, mutect2
- MSH6 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 70/118 reads (59%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1060502878; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLA1 | c.3956C>T p.P1319L | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV100985032; called by muse, mutect2, varscan2
- TPM2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs781030673; called by muse, mutect2, varscan2
- BARD1 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ERICH6 | c.1096C>A p.H366N | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM3 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- LAMA3 | c.6527C>T p.A2176V (on ENST00000313654 / NM_198129.4; = p.A567V on NM_000227.6) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- MGAM | c.5521A>G p.R1841G | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NIN | c.1727C>G p.P576R | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRC5 | c.5164A>C p.S1722R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by mutect2, varscan2
- PCDHB3 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PLCL1 | c.2654A>G p.D885G | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- RADX | c.703C>G p.P235A | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- RIF1 | c.3614C>T p.T1205I | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMD9 | c.3787T>A p.S1263T | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP10D | c.96G>A p.S32= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as rs539663059; called by muse, mutect2, varscan2
- DNAH3 | c.3957G>A p.A1319= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs748188536, COSV54507449; called by mutect2, varscan2
- KCND2 | c.1209G>A p.P403= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as rs139984469; called by muse, mutect2, varscan2
- LCT | c.4053C>T p.S1351= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as rs139528746; called by muse, mutect2, varscan2
- PCDH10 | c.1086C>T p.T362= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- PCDHA11 | c.1782C>T p.R594= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs782085408, COSV100252132; called by muse, mutect2, varscan2
- RYR3 | c.3738C>T p.N1246= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs372929421; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC19A3 | c.1434T>C p.N478= | Silent (SNP) | VAF 34/169 reads (20%) | called by muse, mutect2, varscan2
- SPAG16 | c.1167G>A p.T389= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as rs1446357789; called by muse, mutect2, varscan2
- SPAG9 | c.141C>T p.V47= | Silent (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- SYNE1 | c.10761C>T p.S3587= (on ENST00000367255 / NM_182961.4; = p.S3594= on NM_033071.3) | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as rs201715967; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ZC3H18 | c.276G>A p.P92= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- MAMLD1 | c.*851G>A | 3'UTR (SNP) | VAF 17/78 reads (22%) | catalogued as rs782208172, COSV53380521; called by muse, mutect2, varscan2
- Unknown | chr17:21431436 A>C | IGR (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
